Surgical pathology report (de-identified scan), TCGA case TCGA-YU-AA60, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-AA60-01A (Primary Tumor).

ICD-O-3
Seminoma NOS 9061/3
Site Testis NOS C62.9
9/23/20/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

“Right testis”:

- Classic seminoma.
- Neoplasia size: 5.5 x 3.5 cm.
- Intratubular neoplasia: absent.
- Sanguineous vascular invasion: not detected.
- Lymphatic vascular invasion: not detected.
- Perineural invasion: not detected.
- Rete testis: free of neoplasia.
- Tunica albuginea: free of neoplasia.
- Margin of tunica albuginea: free of neoplasia.
- Adjacent testicular parenchyma: atrophy.

NOTE: New slices are being made to search for possible foci of other histological subtypes, and the results will follow in a complementary report.

Addendum:

“Right testis”:

. New slices were made and only Classic Seminoma was observed in the neoplasia, without any other associated component.

Source: NCI Genomic Data Commons file 264cd6bc-f6e3-43db-ab70-a1a4c869ae17 (TCGA-YU-AA60-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).